Somatic mutation profile of tumor specimen ALCH-B4IU-TTP1-A (aliquot ALCH-B4IU-TTP1-A-1-0-D-A81V-36) from ALCHEMIST case ALCH-B4IU, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Mixed invasive mucinous and non-mucinous adenocarcinoma; Age at diagnosis: 77.2 years (28,193 days).
Specimen ALCH-B4IU-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d28633f8-4742-44f0-936b-3c975140c317.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B4IU-NB1-A (Blood Derived Normal), aliquot ALCH-B4IU-NB1-A-1-0-D-A81V-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7941b664-9e1d-442a-8910-8228181ff9ce

The open-access MAF lists 19 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 13, Silent 3, Splice Site 1, Intron 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACYP1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 12/121 reads (10%) | SIFT tolerated (0.12); catalogued as rs894321447; called by muse, mutect2
- CHAT | c.1130C>T p.S377L | Missense Mutation (SNP) | VAF 21/280 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as rs1451392375, COSV100340285; called by muse, mutect2
- COL6A1 | c.2153G>C p.S718T | Missense Mutation (SNP) | VAF 8/121 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1202683079; called by muse, mutect2
- MFN2 | c.1960A>T p.T654S | Missense Mutation (SNP) | VAF 16/215 reads (7%) | SIFT tolerated (0.23); PolyPhen benign (0.259); catalogued as COSV52421541; called by muse, mutect2
- ZNF280B | c.1348C>T p.H450Y | Missense Mutation (SNP) | VAF 10/281 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.596); catalogued as COSV64529786; called by muse, mutect2
- CCDC40 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 9/259 reads (3%) | SIFT tolerated, low confidence (0.36); PolyPhen benign (0.037); called by muse, mutect2
- DOCK6 | c.2393T>C p.V798A | Missense Mutation (SNP) | VAF 8/85 reads (9%) | SIFT tolerated (0.56); PolyPhen probably damaging (0.935); called by muse, mutect2
- FREM1 | c.2386A>C p.S796R | Missense Mutation (SNP) | VAF 17/228 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.536); called by muse, mutect2
- MCTP1 | c.1876G>C p.G626R | Missense Mutation (SNP) | VAF 32/384 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- NLN | c.2050A>T p.N684Y | Missense Mutation (SNP) | VAF 25/352 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.583); called by muse, mutect2
- PDZD2 | c.8218+1G>C p.X2740_splice | Splice Site (SNP) | VAF 6/87 reads (7%) | called by muse, mutect2
- POMT2 | c.1172A>G p.N391S | Missense Mutation (SNP) | VAF 31/527 reads (6%) | SIFT deleterious (0.04); PolyPhen benign (0.094); called by muse, mutect2
- SRRM3 | c.601A>C p.K201Q | Missense Mutation (SNP) | VAF 8/104 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- ZNF215 | c.411C>A p.C137* | Nonsense Mutation (SNP) | VAF 18/242 reads (7%) | called by muse, mutect2
- ZNF43 | c.1676T>A p.I559N | Missense Mutation (SNP) | VAF 16/290 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- COL9A2 | c.816G>A p.P272= | Silent (SNP) | VAF 30/328 reads (9%) | catalogued as rs767738040, COSV65607368; called by muse, mutect2
- KBTBD3 | c.978A>G p.Q326= | Silent (SNP) | VAF 14/187 reads (7%) | catalogued as rs756921366, COSV101595706; called by muse, mutect2
- MTMR12 | c.1206C>T p.S402= | Silent (SNP) | VAF 10/59 reads (17%) | called by muse, mutect2, varscan2
- SEPTIN7P9 | n.349-927A>T | Intron (SNP) | VAF 18/290 reads (6%) | called by muse, mutect2
